Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-5891, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-5891-01A (Primary Tumor).

[page 1 of 4]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source

Clinical Findings & History:

with right renal mass and caval thrombus.

Specimens Submitted:

- 1: SP: Right kidney, renal vein thrombus, vena caval thrombus; radical nephrectomy
- 2: SP: Portion of right gonadal vein; biopsy
- 3: SP: Para caval and pre caval lymph nodes; excision
- 4: SP: Right renal lymph nodes; excision

DIAGNOSIS:

1. SP: Right kidney, renal vein thrombus, vena caval thrombus; radical nephrectomy:

Tumor Type:

Renal cell carcinoma - Unclassified type
with high nuclear grade; see note

Tumor Size:

Greatest diameter is 12.2 cm.

Local Invasion (for renal cortical types):

Involves renal sinus fat
Involves renal hilar fat

Renal Vein Invasion:

Identified

Tumor is also seen in muscular veins in the region of the renal sinus/hilum

Surgical Margins:

Tumor present at renal vein margin

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3b Tumor grossly extends into the renal vein(s) or vena cava below the diaphragm

Note: The tumor displays predominant papillary and focally solid architecture and is composed of cells with abundant eosinophilic cytoplasm and high nuclear grade. Immunohistochemical stains are strongly positive for racemase and CD10 (the latter in a "luminal" pattern), show patchy positivity for CA-IX, and are negative for CK7, 34BE12, TFE-3, TFE-B and CEA. The combination

[page 2 of 4]
[REDACTED]

of these findings raises a differential diagnosis which includes Type 2 papillary renal cell carcinoma and a tumor of distal nephron origin. This case has been reviewed with [REDACTED] which concurs with the diagnosis.

2. SP: Portion of right gonadal vein; biopsy:
Benign segment of vascular tissue.

3. SP: Para caval and pre caval lymph nodes; excision:

Lymph Nodes:

Not involved

Number of nodes examined: 11

4. SP: Right renal lymph nodes; excision:

Lymph Nodes:

1 ganglioneuroma (1.1cm) and adjacent benign adrenal tissue are seen: no lymph nodes identified

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 and is qualified to perform high complexity clinical laboratory testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]

Special Studies:

Result

Special Stain

Comment

CA-1X.

CD10

RACEMASE

CK7

CEA P

34BE12

IMM RECUT

NEG CONT

IGH

Gross Description:

[REDACTED]

1) The specimen is received fresh labeled "right kidney, renal vein thrombus, vena caval thrombus" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 526 g in total. The kidney measures 12.2 x 8.6 x 6.8 cm. The attached ureter measures 4.5 cm in length and 0.3 cm in diameter. The attached renal vein measures 6.6 cm in length and 1.8 cm in diameter, and is completely filled with tan, friable fleshy tumor mass. The ureter margin is grossly unremarkable. The kidney is inked black and bivalved to reveal a 12.2 x 9.2 x 7.4 cm irregular lobulated, friable tan tumor mass, completely replacing upper pole and mid kidney. The tumor grossly invades into the renal sinus and renal vein. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 0.6 cm. The specimen is photographed. Representative sections are submitted for [REDACTED] and for permanent sections.

Summary of sections:

RAM - renal artery margin

RVM - renal vein margin

UM - ureteral margin

[page 3 of 4]
T-- tumor
RV -- renal vein
THF-- tumor with hilum
TPF -- tumor to perirenal fat
K -- representative section, unaffected kidney

2) The specimen is received in formalin, labeled "portion of right gonadal vein" and consists of a segment of vein measuring 2.1 cm in length and 1.2 cm in average diameter.

Summary of sections:

M--margin

U--representative section of remainder

3) The specimen is received in formalin, labeled "paracaval and precaval lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.4 to 1.8 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes

BLN-- bisected lymph nodes

4) The specimen is received in formalin, labeled "right renal lymph nodes" and consists of a portion of adrenal gland (measuring 3.2 x 2.0 x 0.3 cm) with attached fat measuring 6.2 x 4.7 x 0.8 cm in overall dimension. Possible lymph nodes are also identified. The specimen is representatively submitted.

Summary of sections:

LN -- lymph nodes

TLN-- trisected lymph nodes

ADR--adrenal gland

F--fat

Summary of Sections:

Part 1: SP: Right kidney, renal vein thrombus, vena caval thrombus; radical nephrectomy

Block	Sect. Site	PCs
1	K	1
1	RAM	1
2	RV	2
1	RVM	1
8	T	8
3	THF	3
2	TPF	2
1	UM	1

Part 2: SP: Portion of right gonadal vein; biopsy

Block	Sect. Site	PCs
1	m	1
1	u	1

Part 3: SP: Para caval and pre caval lymph nodes; excision

Block	Sect. Site	PCs
3	bln	3
3	ln	3

Part 4: SP: Right renal lymph nodes; excision

[page 4 of 4]
Block	Sect. Site	PCs
1	adr	1
1	f	1
1	ln	1
1	tlh	1

Source: NCI Genomic Data Commons file 35d29480-9d70-47eb-a7d3-bcd8d545fe79 (TCGA-BQ-5891.104E35BE-852A-491E-A16E-1E13FD6B7582.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).